Surgical pathology report (de-identified scan), TCGA case TCGA-IA-A40X, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Cleveland Clinic, specimen TCGA-IA-A40X-01A (Primary Tumor).

[page 1 of 3]
Results

SURGICAL PATHOLOGY (Order # [redacted])

Patient Info

Patient Name [redacted]

Sex [redacted]

DOB [redacted]

Results

Specimen # [redacted]
Submitting Physician: [redacted]

FINAL DIAGNOSIS

ICD-O-3
renal cell carcinoma, papillary
8260/3
Site: kidney, NOS
C64.9
8-3-12
RD

1. Left kidney, partial nephrectomy (A) - Renal cell carcinoma, papillary type 1 (3.5 cm in greatest dimension), nuclear Furhman grade 2 of 4. (See comment)
- The tumor is confined to the kidney.
- Vascular invasion is not identified.
- The parenchymal and capsular/soft tissue margins of resection are negative for tumor.
2. Left adrenal gland, adrenalectomy (B) - Unremarkable adrenal gland.

COMMENT

Procedure: Partial nephrectomy
Specimen Laterality: Left
Tumor Site: (select all that apply): Upper pole
Tumor Size (Greatest dimension): 3 cm
Tumor Focality: Unifocal
Macroscopic Extent of Tumor: Tumor limited to kidney
Histologic Type: Papillary renal cell carcinoma
Sarcomatoid Features: Not identified
Tumor Necrosis: (any amount) (Optional): Not identified
Histologic Grade: (Furhman Nuclear Grade) 2/4
Microscopic Tumor Extension: (select all that apply): Tumor limited to kidney
Margins: (select all that apply): Margins uninvolved by invasive carcinoma
Lymph-Vascular Invasion: Not identified
Pathologic Findings in Nonneoplastic Kidney: Patchy interstitial chronic

[page 2 of 3]
inflammation; multifocal clear cell changes

Pathologic Stage (pTNM): pT1a NX MX

By immunoperoxidase staining the tumor is positive for AMACR and CK7 and negative for WT-1 and CD 57, supporting the above diagnosis.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the

The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

(Electronic Signature)

SPECIMEN SUBMITTED

A: PARTIAL KIDNEY

B: LEFT ADRENAL

CLINICAL DATA

LEFT RENAL MASS

INTRAOPERATIVE CONSULT DIAGNOSIS

A. Encapsulated neoplasm. Margin is grossly negative (gross diagnosis only). (

GROSS DESCRIPTION

A. Received fresh at the frozen desk labeled "partial nephrectomy" is a segment of kidney measuring 4.0 x 3.5 x 3.0 cm and weighing 26.7 grams. Renal artery, vein, pelvic and ureter are not present in the specimen. A 3.5 x 3.2 x 3.0 cm tan soft encapsulated tumor mass is present within the specimen. The tumor bulges the renal capsule and extends to 0.1 cm from the capsular/soft tissue margin (inked blue). The mass is 0.1 cm from the parenchymal margin of resection (inked black). After gross inspection with the surgeon, a possible frozen section was canceled at the surgeon's request because the parenchymal margin was grossly negative for tumor. Sections are submitted as follows: A1 tumor; A2 uninvolved kidney; A3 tumor with parenchymal and capsular/soft tissue margin; A4 tumor with parenchymal margin; A5-A6 tumor with capsular/soft tissue.

B. Received fresh labeled "left adrenal" is a specimen consisting of an adrenal gland measuring 8 x 4.5 x 1 cm and weighing 20.8 grams. No masses are palpated. The specimen is inked black and serially sectioned. Sectioning reveals unremarkable adrenal parenchyma. Representative sections are submitted in B1-B4.

Patient ID #: [REDACTED]

DOB: [REDACTED] (Age: [REDACTED])

Date of Report: [REDACTED]

[page 3 of 3]
Date of Procedure: [REDACTED]
Date of Receipt: [REDACTED]
Submitted by:
Location:
Test performed by:

Lab and Collection

SURGICAL PATHOLOGY (Order # [REDACTED]) on [REDACTED] - Lab and Collection Information

Result History

SURGICAL PATHOLOGY (Order # [REDACTED]) on [REDACTED] - Order Result History Report.

Result Information

Result Date and Time	Status	Provider Status
[REDACTED]	Final result	Reviewed

tatus:

This result is currently not released to

Display Full Result Report

Display Order Report

Source: NCI Genomic Data Commons file ab38ad3b-fa68-4ace-a9f4-10473a82b346 (TCGA-IA-A40X.F136F750-09F6-45E4-A2D9-58748D4F1799.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).